Somatic mutation profile of tumor specimen TARGET-30-PAUHFW-01A (aliquot TARGET-30-PAUHFW-01A-01D) from TARGET case TARGET-30-PAUHFW, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.2 years (789 days).
Specimen TARGET-30-PAUHFW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07036597-2e5e-4bf3-8955-0ec1e1848817.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUHFW-10A (Blood Derived Normal), aliquot TARGET-30-PAUHFW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fc3174e-14e7-47ae-a92a-a2d25368d722

The open-access MAF lists 3 somatic variants for this specimen: 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP3K4 | c.1689G>A p.K563= | Silent (SNP) | VAF 38/157 reads (24%) | catalogued as COSV62335485; called by muse, mutect2, varscan2
- MKI67 | c.6591G>A p.L2197= | Silent (SNP) | VAF 63/260 reads (24%) | catalogued as COSV100896655, COSV64074773, COSV64075321; called by muse, mutect2, varscan2
- AR | c.*3613A>G | 3'UTR (SNP) | VAF 35/88 reads (40%) | catalogued as COSV65959100; called by muse, mutect2, varscan2
